BEATAML1.0 case 2587 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myelodysplastic Syndromes; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/4fb0b61f-9dfe-4c46-9d96-b289e8ec614c

Demographics
Sex at birth: female.

Diagnoses (1)
1. Refractory cytopenia with multilineage dysplasia: ICD-O-3 morphology code: 9985/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.3 years (21,642 days); Progression or recurrence: no; ELN risk classification: Adverse.

Biospecimens (2 samples)
- Sample BA3059R: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Fresh.
- Sample BA3061D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
